FM case AD5371 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/0bf84b4c-9d7f-405a-b1f8-0c8f39301d41

Male, 63.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the anus; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
